CCDI case PBBUDJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/5891adc3-2f64-4380-8e1e-e6cded73663d

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Sertoli-Leydig cell tumor, poorly differentiated: ICD-O-3 morphology code: 8631/3; Tissue or organ of origin: Ovary; Age at diagnosis: 12.3 years (4,475 days).

Biospecimens (3 samples)
- Sample 0DHFL3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHFLU: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHFN2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
